Surgical pathology report (de-identified scan), TCGA case TCGA-08-0246, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0246-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

A. Brain, left temporal, biopsy: Glioblastoma multiforme, grade IV (WHO); see comment.

B. Brain, left temporal, excision: Glioblastoma multiforme, grade IV (WHO); see comment.

COMMENT: There is nuclear atypia, marked hypercellularity, tumor necrosis and microvascular proliferation seen. Immunoperoxidase stains show that neoplastic cells stain positively for glial fibrillary acidic protein, and there is no significant staining for keratin.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high-complexity clinical testing.

Intraoperative Diagnosis

FS1 (A) Brain, left hemisphere, biopsy: Malignant neoplasm: Glioblastoma versus metastatic tumor.

Gross Description

The specimen is received from the O.R. in two parts, each labeled with the patient's name and medical record number.

Part A is labeled "brain tumor." It consists of a single fragment of tan-pink soft tissue which measures 1.5 x 0.9 x 0.5 cm. One-half of the specimen is frozen in frozen section #1 and subsequently submitted in cassette A1. A portion of the remainder is frozen for research, and the rest submitted in cassette A2.

Part B is labeled "brain tumor, left temporal," and consists of multiple moderately firm, tan-white, and

[page 2 of 2]
focally hemorrhagic fragment of tissue measuring 5.1 x 2.4 x 1.7 cm. Aggressive. Representative sections are submitted. Assets B1-B5.

Clinical History

The patient is a [REDACTED] who has a left hemispheric mass. The clinical suspicion is high-grade glioma. The specimen appears to be ~6.0 cm in greatest dimension by imaging.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 6b8b4c70-2921-47cf-a3bf-12ead87932b5 (TCGA-08-0246.41C276A4-B311-4478-A6B0-B214F95A50C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).